HCMI case HCM-BROD-0040-C74 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Adrenal gland. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/faf9731f-8d64-45d6-8bfc-7d5183243904

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 2013; Vital status: Alive.

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; ICD-10 code: C74.9; Tissue or organ of origin: Adrenal gland, NOS; Site of resection or biopsy: Pleura, NOS; Classification of tumor: primary; Age at diagnosis: 2.8 years (1,030 days); Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Prior treatment: No; Cog neuroblastoma risk group: High Risk; Inpc grade: Poorly Differentiated; Inpc histologic group: Unfavorable; INRG stage: M; Mitosis karyorrhexis index: Low; Sites of involvement: Pleura.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Vincristine; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 0 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Etoposide; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 31 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Doxorubicin Hydrochloride; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 45 days.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Dinutuximab; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 92 days.
   Treatment given: Treatment type: Radiation, Proton Beam; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 273 days.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Targeted Molecular Therapy, for residual disease.

Follow-up (2 entries)
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Pleura, NOS; Days to progression: 0 days.
- Follow-up contact recording only the day: day 516.

Molecular and laboratory tests
- MYCN amplification: Not Amplified.

Other clinical attributes
- Timepoint category: Initial Diagnosis; BMI: 15.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relationship type: First Degree Relative, NOS.

Biospecimens (2 samples)
- Sample HCM-BROD-0040-C74-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample HCM-BROD-0040-C74-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 7.
